EXCEPTIONAL_RESPONDERS case ER-ABON — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8948f276-383a-4011-9826-45de1cbb0f77

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Year of birth: 1943; Vital status: Alive.

Diagnoses (1)
1. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 65.2 years (23,811 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 2,263 days (6.2 years); Days to best overall response: 268 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Fluorouracil + Leucovorin Calcium; Days to treatment start: 30 days; Days to treatment end: 63 days.
   Treatment given: Therapeutic agents: Oxaliplatin; Days to treatment start: 30 days; Days to treatment end: 254 days.
   Treatment given: Therapeutic agents: Bevacizumab; Days to treatment start: 63 days; Days to treatment end: 63 days.
   Treatment given: Therapeutic agents: Capecitabine; Days to treatment start: 81 days; Days to treatment end: 102 days.
   Treatment given: Therapeutic agents: Bevacizumab; Days to treatment start: 102 days; Days to treatment end: 316 days.
   Treatment given: Therapeutic agents: Fluorouracil; Days to treatment start: 123 days; Days to treatment end: 316 days.
   Treatment given: Therapeutic agents: Not Otherwise Specified; Days to treatment start: 123 days; Days to treatment end: 170 days.
   Treatment given: Therapeutic agents: Leucovorin Calcium; Days to treatment start: 190 days; Days to treatment end: 316 days.

Follow-up (1 entry)
- Days to follow up: 2,263 days (6.2 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 2,263 days (6.2 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABON-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-ABON-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 60; Percent normal cells: 15; Percent necrosis: 10; Percent stromal cells: 0; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-ABON-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-ABON-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 5; Percent normal cells: 50; Percent necrosis: 25; Percent stromal cells: 0; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
